Somatic mutation profile of tumor specimen TCGA-AX-A06F-01A (aliquot TCGA-AX-A06F-01A-11W-A027-09) from TCGA case TCGA-AX-A06F, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 59.2 years (21,624 days).
Specimen TCGA-AX-A06F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d9c827-11eb-44d8-bcb1-2b6699e0fb20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A06F-10A (Blood Derived Normal), aliquot TCGA-AX-A06F-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aec970d-321d-4f29-bc19-aa24b4ea9f36

The open-access MAF lists 9,129 somatic variants for this specimen: 6,838 protein-altering or splice-affecting, 2,083 silent, 208 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,142, Silent 2,083, Nonsense Mutation 472, Splice Site 131, Intron 84, RNA 57, Splice Region 56, 3'Flank 20, 3'UTR 20, 5'Flank 19, Frame Shift Ins 15, Frame Shift Del 13.

Variants (750 of 9,129; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370720208, CM075969; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 165/207 reads (80%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSA | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); catalogued as rs74315467, CM930039, COSV99332470; ClinVar: pathogenic; called by muse, varscan2
- BRCA2 | c.1909+1G>A p.X637_splice | Splice Site (SNP) | VAF 52/147 reads (35%) | catalogued as rs587781629, COSV66464373; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNGB1 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 98/243 reads (40%) | catalogued as rs1352458826, COSV51906385; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 94/236 reads (40%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 86/178 reads (48%) | catalogued as rs267606777, CM061705, COSV57389289; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.5984C>T p.A1995V | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs963717773, COSV62086278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELOVL4 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 70/199 reads (35%) | catalogued as rs387906916, CM1110104, COSV63953609; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EPHB1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 233/561 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1338928289, COSV67655119; called by muse, mutect2, varscan2
- FBN1 | c.5183C>T p.A1728V | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1131691804, CM115514, COSV100356139; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 210/495 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ILDR1 | c.1384C>T p.R462* (on ENST00000344209 / NM_001199799.2; = p.R418* on NM_175924.4) | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs775062249, COSV99878817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.2563C>T p.R855* (on ENST00000642864 / NM_001111125.3; = p.R650* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs587777261, CM129316, COSV64724818; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB3 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 50/130 reads (38%) | catalogued as rs121918450, CM973033; ClinVar: pathogenic; called by muse, varscan2
- L1CAM | c.924C>T p.G308= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs797044787, CS982242, COSV100648896; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.2439G>A p.W813* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs121908032, CM850008, COSV99370253; ClinVar: pathogenic; called by muse, varscan2
- MCCC1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754460336, COSV99660015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs28935468, CM993354, COSV100318414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779617676, CM144063, COSV52274821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 90/225 reads (40%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 104/258 reads (40%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- OTC | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs72558489, CM971116, COSV99234315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDE6A | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 65/160 reads (41%) | catalogued as rs146591309, CM066961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 109/279 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 24/46 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205227, CM153572, COSV59042121; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 364/455 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | catalogued as rs975191415, CM083068, COSV57191619; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RRM2B | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.597); catalogued as rs515726186, CM0910814, COSV52566610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.10939G>T p.E3647* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as rs1156566314, COSV66538422, COSV66541147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC22A5 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749282641, CM102258, COSV55372307; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, varscan2
- TGFBR2 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057524810, CM1010163, COSV55443564, COSV55445471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.45160C>T p.R15054* (on ENST00000591111; = p.R7630* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as rs751502842, COSV100592805, COSV59935923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UPF3B | c.1288C>T p.R430* (on ENST00000276201 / NM_080632.3; = p.R417* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 234/570 reads (41%) | catalogued as rs122468181, CM074621, COSV52229788; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- USH2A | c.10074C>A p.C3358* | Nonsense Mutation (SNP) | VAF 148/384 reads (39%) | catalogued as rs1403618793, COSV100240617; ClinVar: pathogenic; called by muse, varscan2
- A2ML1 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.41); catalogued as COSV100229305; called by muse, mutect2, varscan2
- A2ML1 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100229309; called by muse, mutect2, varscan2
- A2ML1 | c.2031C>T p.D677= | Splice Region (SNP) | VAF 190/477 reads (40%) | catalogued as rs373281171; called by muse, mutect2, varscan2
- A4GNT | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599622, COSV52628852; called by muse, mutect2, varscan2
- AACS | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs207473450, COSV99908231; called by muse, mutect2, varscan2
- AARS1 | c.1236G>T p.W412C | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV55747547, COSV99933712; called by muse, mutect2, varscan2
- AARS2 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs544333323, COSV55113682; called by muse, mutect2, varscan2
- AARS2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99771628; called by muse, mutect2, varscan2
- AASDH | c.1879C>A p.L627I | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99221721; called by muse, mutect2, varscan2
- AASDHPPT | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99593405; called by muse, mutect2, varscan2
- ABCA1 | c.4331C>T p.T1444I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV101037499; called by muse, mutect2, varscan2
- ABCA1 | c.3730C>A p.L1244M | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101037500; called by muse, varscan2
- ABCA1 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV101037501; called by muse, varscan2
- ABCA1 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV101037503; called by muse, mutect2, varscan2
- ABCA10 | c.4476G>A p.A1492= | Splice Region (SNP) | VAF 93/224 reads (42%) | catalogued as rs762539015, COSV99288884, COSV99289186; called by muse, mutect2, varscan2
- ABCA10 | c.4389G>A p.W1463* | Nonsense Mutation (SNP) | VAF 76/173 reads (44%) | catalogued as rs1404725532, COSV99289190; called by muse, mutect2, varscan2
- ABCA10 | c.3116G>A p.R1039H | Missense Mutation (SNP) | VAF 140/403 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs762850142, COSV52219190; called by muse, mutect2, varscan2
- ABCA10 | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV52219460; called by muse, mutect2, varscan2
- ABCA10 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99289196; called by muse, mutect2, varscan2
- ABCA13 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV101330152; called by muse, mutect2, varscan2
- ABCA13 | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101330153; called by muse, mutect2, varscan2
- ABCA13 | c.4024G>T p.D1342Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.391); catalogued as COSV101330119, COSV70043390; called by muse, mutect2, varscan2
- ABCA13 | c.10079G>A p.R3360K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.164); catalogued as COSV101447154, COSV71285638; called by muse, mutect2, varscan2
- ABCA13 | c.12215C>T p.T4072I | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV101447155; called by muse, mutect2, varscan2
- ABCA13 | c.13585G>T p.A4529S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101291414; called by muse, mutect2, varscan2
- ABCA13 | c.13921G>A p.G4641S | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1431668703, COSV68949214; called by muse, mutect2, varscan2
- ABCA3 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs745530191, COSV100069006; called by muse, varscan2
- ABCA5 | c.3639G>A p.S1213= | Splice Region (SNP) | VAF 32/103 reads (31%) | catalogued as rs778958910, COSV67018547; called by muse, mutect2, varscan2
- ABCA6 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV99447437; called by muse, mutect2, varscan2
- ABCA6 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 178/461 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.361); catalogued as COSV52639826; called by muse, mutect2, varscan2
- ABCA8 | c.3715G>A p.V1239I | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV99285660; called by muse, mutect2, varscan2
- ABCA8 | c.2961C>A p.F987L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV99286645; called by muse, mutect2
- ABCA8 | c.1735C>A p.L579I | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99286648; called by muse, mutect2, varscan2
- ABCA8 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1463211055, COSV99286651; called by muse, mutect2, varscan2
- ABCA9 | c.3244C>T p.L1082F | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.443); catalogued as COSV60627798; called by muse, mutect2, varscan2
- ABCB1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200754866, COSV55952144; called by muse, mutect2, varscan2
- ABCB1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs754765644, COSV55948559; called by muse, mutect2, varscan2
- ABCB10 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV100748055; called by muse, mutect2, varscan2
- ABCB11 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1192578960, COSV55588431; called by muse, mutect2, varscan2
- ABCB5 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99329288; called by muse, varscan2
- ABCB5 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759211780, COSV51706669; called by muse, mutect2, varscan2
- ABCB5 | c.1684G>T p.A562S (on ENST00000404938 / NM_001163941.2; = p.A117S on NM_178559.6) | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV99329291; called by muse, mutect2, varscan2
- ABCC1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV60694395; called by muse, mutect2, varscan2
- ABCC1 | c.2985G>A p.W995* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100580203; called by muse, mutect2, varscan2
- ABCC2 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100965642; called by muse, mutect2, varscan2
- ABCC2 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100966662; called by muse, mutect2, varscan2
- ABCC2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747449108, COSV64985390; called by muse, mutect2, varscan2
- ABCC3 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as COSV99559657; called by muse, mutect2, varscan2
- ABCC3 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as rs759534433, COSV53319352; called by muse, mutect2, varscan2
- ABCC4 | c.3481G>T p.D1161Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100972717; called by muse, mutect2, varscan2
- ABCC4 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs1246870484, COSV65310949; called by muse, mutect2, varscan2
- ABCC4 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV100972719; called by muse, mutect2, varscan2
- ABCC5 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV99657405; called by muse, mutect2
- ABCC6 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99229460; called by muse, mutect2, varscan2
- ABCC9 | c.3554T>A p.I1185N | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99686762; called by muse, mutect2, varscan2
- ABCC9 | c.3265C>A p.L1089M | Missense Mutation (SNP) | VAF 154/441 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53985739, COSV99686764; called by muse, mutect2, varscan2
- ABCC9 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 191/482 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99686769; called by muse, mutect2, varscan2
- ABCD1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99497852; called by muse, mutect2, varscan2
- ABCD3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100239044; called by muse, mutect2, varscan2
- ABCF3 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99490877; called by muse, mutect2, varscan2
- ABCF3 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 62/115 reads (54%) | catalogued as COSV99490879; called by muse, mutect2, varscan2
- ABCF3 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775699975, COSV99491622; called by muse, mutect2, varscan2
- ABCG2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 227/587 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs961438533, COSV52944493, COSV52945379, COSV99419957; called by muse, mutect2, varscan2
- ABHD12 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.713); catalogued as rs199647442, COSV100194766; called by muse, varscan2
- ABHD13 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs749263953, COSV101024240, COSV65534301; called by muse, mutect2, varscan2
- ABHD16A | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101013331, COSV65451512; called by muse, mutect2, varscan2
- ABHD2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100756425; called by muse, mutect2, varscan2
- ABHD3 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV100004537; called by muse, mutect2, varscan2
- ABHD4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs146234194; called by muse, mutect2, varscan2
- ABITRAM | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100336691; called by muse, mutect2, varscan2
- ABL2 | c.2009G>A p.S670N (on ENST00000502732 / NM_007314.4; = p.S655N on NM_005158.5) | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100772925; called by muse, mutect2, varscan2
- ABLIM1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 110/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769723095, COSV99522016; called by muse, varscan2
- ABLIM1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 134/314 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs1322528617, COSV53299667; called by muse, varscan2
- ABLIM3 | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100448710; called by muse, mutect2, varscan2
- ABRAXAS1 | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as COSV99788342, COSV99788593; called by muse, mutect2, varscan2
- ABRAXAS1 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV99788594; called by muse, mutect2, varscan2
- ABRAXAS1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV58950900; called by muse, mutect2, varscan2
- AC005833.1 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV99363159; called by muse, mutect2, varscan2
- AC008397.2 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs146406381; called by muse, mutect2, varscan2
- AC011462.1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs768944277, COSV54199618; called by muse, mutect2, varscan2
- AC090517.4 | c.1891G>A p.V631I | Missense Mutation (SNP) | VAF 214/575 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as rs1211093781, COSV99974986; called by muse, mutect2, varscan2
- AC090517.4 | c.89A>C p.E30A | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99974995; called by muse, mutect2, varscan2
- AC109583.1 | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs1485404180, COSV100167959; called by muse, mutect2, varscan2
- AC126283.2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101143985; called by muse, mutect2, varscan2
- AC127029.3 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100033172, COSV100033338; called by muse, mutect2, varscan2
- AC244197.3 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as COSV100558158; called by muse, mutect2, varscan2
- ACAD10 | c.918T>G p.N306K | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.096); catalogued as COSV100564513; called by muse, mutect2, varscan2
- ACAD8 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as COSV99844521; called by muse, mutect2, varscan2
- ACAD8 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99844523; called by muse, mutect2, varscan2
- ACADSB | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100715287; called by muse, mutect2, varscan2
- ACAN | c.6035C>T p.T2012I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.561); catalogued as COSV100719021; called by muse, mutect2, varscan2
- ACCSL | c.279A>C p.Q93H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV101122271; called by muse, mutect2, varscan2
- ACE | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52006369; called by muse, varscan2
- ACE | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1325764936, COSV99327578; called by muse, mutect2
- ACE | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004764; called by muse, mutect2, varscan2
- ACER1 | c.627-1G>A p.X209_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100034102; called by muse, mutect2, varscan2
- ACKR3 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV99799761; called by muse, mutect2, varscan2
- ACKR4 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 80/462 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99031675; called by mutect2, varscan2
- ACO2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs534016929, COSV53441699; called by muse, mutect2, varscan2
- ACO2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as rs147361669, COSV99347680; called by muse, mutect2, varscan2
- ACOT12 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100297115; called by muse, mutect2, varscan2
- ACOT9 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV100321421; called by muse, mutect2, varscan2
- ACOX1 | c.1479-1G>A p.X493_splice | Splice Site (SNP) | VAF 44/109 reads (40%) | catalogued as COSV99503914; called by muse, mutect2, varscan2
- ACOX2 | c.1580A>G p.D527G | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs1365457575, COSV100250269; called by muse, mutect2, varscan2
- ACOXL | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490570; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ACSL3 | c.1725G>T p.K575N | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100658070; called by muse, mutect2, varscan2
- ACSL4 | c.196G>A p.D66N (on ENST00000340800 / NM_022977.2; = p.D25N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs1363259105, COSV61613928; called by muse, mutect2, varscan2
- ACSL5 | c.1229G>A p.G410D (on ENST00000354273; = p.G466D on NM_016234.3) | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61128587; called by muse, varscan2
- ACSL5 | c.1241G>A p.R414H (on ENST00000354273; = p.R470H on NM_016234.3) | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs750810266, COSV100634750; called by muse, varscan2
- ACSL6 | c.1642G>T p.G548* (on ENST00000379240; = p.G573* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 73/155 reads (47%) | catalogued as COSV57296808, COSV99734470; called by muse, mutect2, varscan2
- ACSM2B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 209/540 reads (39%) | catalogued as COSV61657257; called by muse, mutect2, varscan2
- ACSM4 | c.185G>A p.W62* | Nonsense Mutation (SNP) | VAF 143/354 reads (40%) | catalogued as COSV101257306; called by muse, mutect2, varscan2
- ACSM5 | c.244A>G p.N82D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100089409; called by muse, mutect2, varscan2
- ACSM5 | c.954C>A p.C318* | Nonsense Mutation (SNP) | VAF 240/616 reads (39%) | catalogued as COSV100089412; called by muse, mutect2, varscan2
- ACTC1 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99292079; called by muse, mutect2, varscan2
- ACTC1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV51758756; called by muse, mutect2, varscan2
- ACTG1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100112039; called by muse, mutect2, varscan2
- ACTL6B | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); catalogued as COSV99355710; called by muse, mutect2, varscan2
- ACTL7A | c.1234T>G p.F412V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453199; called by muse, mutect2, varscan2
- ACTL7B | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101012570, COSV101012608; called by muse, mutect2, varscan2
- ACTN1 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV99518375; called by muse, mutect2, varscan2
- ACTR6 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV99498736; called by muse, mutect2, varscan2
- ACTR8 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99213855; called by muse, mutect2, varscan2
- ACTRT1 | c.351A>C p.E117D | Missense Mutation (SNP) | VAF 400/1006 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.418); catalogued as COSV100947720; called by muse, varscan2
- ACVR2A | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV54020019; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 138/418 reads (33%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101188090; called by muse, mutect2, varscan2
- ADA2 | c.1348G>T p.G450C (on ENST00000262607; = p.G209C on NM_177405.3) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206824905, COSV99376378; called by muse, mutect2, varscan2
- ADAD1 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 199/526 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99636114; called by muse, varscan2
- ADAM12 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as rs769115498, COSV64133210; called by muse, mutect2, varscan2
- ADAM18 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696000; called by muse, mutect2, varscan2
- ADAM2 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55860357, COSV99697761; called by muse, mutect2, varscan2
- ADAM20 | c.2073G>C p.L691F | Missense Mutation (SNP) | VAF 271/710 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV99833553; called by muse, mutect2, varscan2
- ADAM22 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV55977238; called by muse, mutect2, varscan2
- ADAM28 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.762); catalogued as rs1392638105, COSV56099330, COSV56100596; called by muse, mutect2, varscan2
- ADAM28 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 145/343 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as rs760421202, COSV56097662; called by muse, varscan2
- ADAM28 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99739604; called by muse, mutect2, varscan2
- ADAM29 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 237/607 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100822213; called by muse, mutect2, varscan2
- ADAM32 | c.1821T>G p.V607= | Splice Region (SNP) | VAF 122/285 reads (43%) | catalogued as COSV101165461; called by muse, mutect2, varscan2
- ADAMTS10 | c.2371C>A p.L791M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99547329; called by muse, mutect2, varscan2
- ADAMTS10 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54353820; called by muse, mutect2, varscan2
- ADAMTS10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | catalogued as COSV99546265; called by muse, mutect2, varscan2
- ADAMTS16 | c.751A>G p.R251G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99942491; called by muse, mutect2, varscan2
- ADAMTS16 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56976773, COSV56980243; called by muse, varscan2
- ADAMTS16 | c.2503A>G p.N835D | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99942495; called by muse, varscan2
- ADAMTS18 | c.3449G>A p.C1150Y | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273855; called by muse, mutect2, varscan2
- ADAMTS18 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as rs747773771, COSV51398816; called by muse, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by muse, varscan2
- ADAMTS19 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 141/370 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV50794658; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 168/213 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTS5 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99538175; called by muse, mutect2, varscan2
- ADARB1 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100654056; called by muse, varscan2
- ADARB1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100654057; called by muse, varscan2
- ADCY1 | c.2753A>C p.K918T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99812749; called by muse, mutect2, varscan2
- ADCY10 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs202210889, COSV63240802; called by muse, mutect2, varscan2
- ADCY2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs372373069; called by muse, mutect2, varscan2
- ADCY2 | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs939197939, COSV57859054, COSV57897856; called by muse, mutect2, varscan2
- ADCY6 | c.2521A>G p.M841V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs780309120, COSV100326817; called by muse, mutect2, varscan2
- ADCY6 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758181397, COSV100326820; called by muse, varscan2
- ADCY7 | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV99576295; called by muse, mutect2, varscan2
- ADCY8 | c.3595C>A p.L1199I | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99653777; called by muse, mutect2, varscan2
- ADCY8 | c.3098T>G p.I1033S | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653780; called by muse, mutect2, varscan2
- ADCY9 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.92); catalogued as rs997238587, COSV53582204; called by muse, mutect2, varscan2
- ADCY9 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV53573911, COSV53581701; called by muse, mutect2, varscan2
- ADCY9 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99570710; called by muse, mutect2
- ADD1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs746365939, COSV99296893; called by muse, mutect2, varscan2
- ADD2 | c.1741+2T>C p.X581_splice | Splice Site (SNP) | VAF 30/144 reads (21%) | catalogued as COSV52459083; called by muse, mutect2, varscan2
- ADGRA1 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV101192734; called by muse, mutect2, varscan2
- ADGRA3 | c.3703C>T p.P1235S | Missense Mutation (SNP) | VAF 127/286 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99293701; called by muse, mutect2, varscan2
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- ADGRE2 | c.2156G>A p.S719N | Missense Mutation (SNP) | VAF 140/326 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1318923879, COSV100216418, COSV59696908; called by muse, varscan2
- ADGRE5 | c.1138C>T p.R380C (on ENST00000242786 / NM_078481.4; = p.R287C on NM_001784.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs367751456; called by muse, mutect2, varscan2
- ADGRF2 | c.913A>T p.N305Y (on ENST00000296862 / NM_001368115.2; = p.N237Y on NM_153839.7) | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV57287517, COSV99731620; called by muse, mutect2, varscan2
- ADGRF5 | c.3751T>G p.F1251V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458295456, COSV99346241; called by muse, mutect2, varscan2
- ADGRG1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs746514384, COSV65636176; called by muse, mutect2, varscan2
- ADGRG4 | c.4828G>A p.V1610I | Missense Mutation (SNP) | VAF 361/969 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99796392; called by muse, mutect2, varscan2
- ADGRG4 | c.6461C>A p.S2154Y | Missense Mutation (SNP) | VAF 173/418 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99796396; called by muse, mutect2, varscan2
- ADGRG5 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV100446490; called by muse, mutect2, varscan2
- ADGRG6 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.307); catalogued as COSV99748296; called by muse, mutect2, varscan2
- ADGRG6 | c.2937G>T p.W979C | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51586730; called by muse, mutect2, varscan2
- ADGRL2 | c.1023T>G p.D341E | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV99590960; called by muse, mutect2, varscan2
- ADGRL2 | c.1560C>A p.N520K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99590963; called by muse, varscan2
- ADGRL2 | c.2488C>A p.L830I (on ENST00000370717 / NM_001366005.1; = p.L817I on NM_012302.4) | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54684441, COSV99590968; called by muse, mutect2, varscan2
- ADGRL2 | c.2628G>T p.Q876H (on ENST00000370717 / NM_001366005.1; = p.Q863H on NM_012302.4) | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as COSV99590974; called by muse, mutect2, varscan2
- ADGRL2 | c.2924G>A p.S975N (on ENST00000370717 / NM_001366005.1; = p.S962N on NM_012302.4) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99590976; called by muse, mutect2, varscan2
- ADGRL4 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.305); catalogued as rs1430793657, COSV100876448, COSV66059809; called by muse, mutect2, varscan2
- ADGRV1 | c.6292C>A p.L2098I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101316349; called by muse, varscan2
- ADGRV1 | c.16130G>A p.G5377E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV67987091, COSV67987614; called by muse, mutect2, varscan2
- ADGRV1 | c.16219T>C p.F5407L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101316350; called by muse, mutect2, varscan2
- ADGRV1 | c.17063G>A p.R5688Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs374682222; called by muse, mutect2, varscan2
- ADH1A | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 228/590 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99265948; called by muse, mutect2, varscan2
- ADH1B | c.1079T>C p.F360S | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100520843; called by muse, mutect2, varscan2
- ADH5 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1213065063, COSV99596341; called by muse, mutect2, varscan2
- ADH6 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99422756; called by muse, mutect2, varscan2
- ADIPOR1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV100579629; called by muse, mutect2, varscan2
- ADIPOR1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100579632; called by muse, varscan2
- ADIPOR2 | c.592T>G p.S198A | Missense Mutation (SNP) | VAF 181/451 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100840170; called by muse, mutect2, varscan2
- ADPGK | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); catalogued as COSV100295343; called by muse, mutect2, varscan2
- ADPRH | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100813314; called by muse, mutect2, varscan2
- ADRB2 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs767978574, COSV100019316; called by muse, mutect2
- ADSS2 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs143745314, COSV100836892; called by muse, mutect2, varscan2
- AEN | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.68); catalogued as COSV100237585; called by muse, mutect2, varscan2
- AFAP1 | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100632035; called by muse, mutect2, varscan2
- AFAP1 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV100632036; called by muse, mutect2, varscan2
- AFF1 | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100320981; called by muse, mutect2, varscan2
- AFF3 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs763782134, COSV100419865; called by muse, mutect2, varscan2
- AFF4 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.427); catalogued as COSV99535267; called by muse, mutect2, varscan2
- AFG3L2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1438358338, COSV52317088; called by muse, mutect2, varscan2
- AFMID | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV100015081; called by muse, mutect2, varscan2
- AGAP3 | c.1758G>T p.E586D (on ENST00000622464; = p.E622D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101257363; called by muse, mutect2, varscan2
- AGAP6 | c.1823C>T p.A608V (on ENST00000374056 / NM_001365867.1; = p.A631V on NM_001077665.2) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100929130; called by muse, mutect2, varscan2
- AGBL2 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100102016; called by muse, mutect2, varscan2
- AGFG1 | c.264C>A p.V88= | Splice Region (SNP) | VAF 75/187 reads (40%) | catalogued as COSV100029109; called by muse, mutect2, varscan2
- AGFG1 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100029114; called by muse, mutect2, varscan2
- AGL | c.4523C>T p.A1508V | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1281888270, COSV99649898; called by muse, mutect2, varscan2
- AGO2 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1156411831, COSV99596240; called by muse, mutect2, varscan2
- AGO3 | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.501); catalogued as COSV99869230; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 63/163 reads (39%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGO4 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs752255596, COSV64617850; called by muse, mutect2, varscan2
- AGPAT4 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100211875; called by muse, mutect2
- AGXT2 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 180/480 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs766572860, COSV99183854; called by muse, mutect2, varscan2
- AHCTF1 | c.553C>T p.R185* (on ENST00000366508; = p.R159* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | catalogued as COSV58252336; called by muse, mutect2, varscan2
- AHCYL1 | c.900-1G>T p.X300_splice | Splice Site (SNP) | VAF 90/224 reads (40%) | catalogued as COSV100779653; called by muse, mutect2, varscan2
- AHNAK | c.15991C>A p.L5331I | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV99949049; called by muse, mutect2, varscan2
- AHNAK | c.15090G>A p.M5030I | Missense Mutation (SNP) | VAF 146/379 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.155); catalogued as COSV99949058; called by muse, mutect2, varscan2
- AHNAK | c.9400A>G p.I3134V | Missense Mutation (SNP) | VAF 214/536 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV57231130; called by muse, mutect2, varscan2
- AHRR | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100327858; called by muse, mutect2, varscan2
- AIFM1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99781345; called by muse, mutect2, varscan2
- AIFM1 | c.198T>A p.N66K | Missense Mutation (SNP) | VAF 192/497 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99781350; called by muse, mutect2, varscan2
- AIM2 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100931130; called by muse, mutect2, varscan2
- AIMP1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs143219988; called by muse, mutect2, varscan2
- AIMP1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100786208; called by muse, mutect2, varscan2
- AIMP2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140208111, COSV99551988; called by muse, mutect2, varscan2
- AKAP1 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV100028212; called by muse, varscan2
- AKAP11 | c.4181G>T p.R1394I | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99214243; called by muse, mutect2, varscan2
- AKAP12 | c.2729C>A p.S910Y | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99484187; called by muse, mutect2, varscan2
- AKAP12 | c.4876G>T p.A1626S | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99484193; called by muse, mutect2, varscan2
- AKAP13 | c.7166G>A p.C2389Y (on ENST00000394518 / NM_007200.5; = p.C2393Y on NM_006738.6) | Missense Mutation (SNP) | VAF 348/832 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100774355; called by muse, varscan2
- AKAP13 | c.7216C>T p.L2406F (on ENST00000394518 / NM_007200.5; = p.L2410F on NM_006738.6) | Missense Mutation (SNP) | VAF 339/926 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV100774356; called by muse, varscan2
- AKAP13 | c.7576G>A p.V2526I (on ENST00000394518 / NM_007200.5; = p.V2530I on NM_006738.6) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100774358; called by muse, mutect2, varscan2
- AKAP17A | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV58312368; called by muse, mutect2, varscan2
- AKAP3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1449396924, COSV99962541; called by muse, mutect2, varscan2
- AKAP6 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99803604; called by muse, mutect2, varscan2
- AKAP8 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs371961765; called by muse, mutect2, varscan2
- AKAP9 | c.3097G>T p.G1033* | Nonsense Mutation (SNP) | VAF 101/268 reads (38%) | catalogued as COSV100662896; called by muse, mutect2, varscan2
- AKAP9 | c.5540C>A p.T1847N (on ENST00000359028; = p.T1815N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100662897; called by muse, mutect2, varscan2
- AKNA | c.3620C>A p.A1207D | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV56340201; called by muse, mutect2, varscan2
- AKNA | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV56311251, COSV56314088; called by muse, mutect2, varscan2
- AKNAD1 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as rs747543823, COSV62198743; called by muse, varscan2
- AKR1B1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV99605379; called by muse, mutect2, varscan2
- AKR1C3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140613308; called by muse, mutect2, varscan2
- AKR1D1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs779758762, COSV54339065; called by muse, mutect2, varscan2
- AKT3 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV55631438; called by muse, mutect2, varscan2
- AL592490.1 | c.1572A>T p.Q524H | Missense Mutation (SNP) | VAF 163/395 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101308263; called by muse, mutect2, varscan2
- AL669918.1 | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs763832575, COSV101441061; called by muse, mutect2, varscan2
- ALAS1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100050456; called by muse, varscan2
- ALAS1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100050457; called by muse, varscan2
- ALAS1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs773796345, COSV59630314; called by muse, mutect2, varscan2
- ALB | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892038; called by muse, mutect2, varscan2
- ALDH16A1 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99513154; called by muse, mutect2, varscan2
- ALDH18A1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.892); catalogued as rs368147360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH18A1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV64663956; called by muse, mutect2, varscan2
- ALDH1L1 | c.1688C>A p.P563H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99857359; called by muse, mutect2, varscan2
- ALDH3B2 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100824106; called by muse, varscan2
- ALDH4A1 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV51895662; called by muse, mutect2, varscan2
- ALDOB | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV100878914; called by muse, mutect2, varscan2
- ALG5 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379722225, COSV53504483; called by muse, mutect2, varscan2
- ALG8 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402505206, COSV55200797; called by muse, mutect2, varscan2
- ALG8 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs763258107, COSV55201130; called by muse, varscan2
- ALK | c.4156T>G p.C1386G | Missense Mutation (SNP) | VAF 157/373 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101202541; called by muse, mutect2, varscan2
- ALK | c.2051T>C p.L684P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV101202542; called by muse, mutect2, varscan2
- ALKBH7 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV99831785; called by muse, varscan2
- ALOX12B | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100047606; called by muse, mutect2, varscan2
- ALOX15B | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205691; called by muse, mutect2, varscan2
- ALPI | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV99786118; called by muse, mutect2, varscan2
- ALPK1 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561659863, COSV99454982; called by muse, mutect2, varscan2
- ALPK1 | c.2004G>T p.Q668H | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99454986; called by muse, mutect2, varscan2
- ALPK2 | c.4793C>A p.P1598H | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100864727; called by muse, mutect2, varscan2
- ALPK2 | c.4146G>T p.K1382N | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100864728; called by muse, mutect2, varscan2
- ALPK2 | c.103A>C p.I35L | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100864730; called by muse, mutect2, varscan2
- ALS2 | c.3965C>A p.A1322D | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV51893499, COSV99969896; called by muse, mutect2, varscan2
- ALS2 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 70/199 reads (35%) | catalogued as COSV99969900; called by muse, varscan2
- AMBP | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs748722080, COSV99468781; called by muse, mutect2, varscan2
- AMFR | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99316162; called by muse, mutect2, varscan2
- AMHR2 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as COSV99143470; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMMECR1 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 223/562 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV99467089; called by muse, mutect2, varscan2
- AMPD1 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 148/395 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs192509679, COSV100815186; called by muse, mutect2, varscan2
- AMPH | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100343278; called by muse, mutect2, varscan2
- AMPH | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100343283; called by muse, mutect2, varscan2
- AMY2A | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 203/267 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101340664; called by muse, mutect2, varscan2
- AMY2A | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 321/1051 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1258113759, COSV101340665; called by muse, mutect2, varscan2
- AMY2B | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100796457; called by muse, mutect2, varscan2
- ANAPC1 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs772338494, COSV61977492; called by muse, mutect2, varscan2
- ANAPC1 | c.1229A>C p.D410A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100595013; called by muse, varscan2
- ANAPC5 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV99946405; called by muse, mutect2, varscan2
- ANAPC5 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.059); catalogued as COSV99946407; called by muse, mutect2, varscan2
- ANGEL2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1195351530, COSV100853984; called by muse, mutect2, varscan2
- ANGPT4 | c.1287C>A p.S429R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV101124850; called by muse, mutect2, varscan2
- ANGPTL1 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99328340; called by muse, mutect2, varscan2
- ANGPTL8 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV99371080; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 205/485 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK2 | c.8188C>T p.P2730S | Missense Mutation (SNP) | VAF 131/341 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs749720688, COSV100003581; called by muse, mutect2, varscan2
- ANK3 | c.9887C>A p.A3296D | Missense Mutation (SNP) | VAF 150/393 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV99781784; called by muse, mutect2, varscan2
- ANK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.333); catalogued as rs538354013, COSV55048293; called by muse, varscan2
- ANK3 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781789; called by muse, mutect2, varscan2
- ANKDD1A | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1176412100, COSV100731274; called by muse, mutect2, varscan2
- ANKFY1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1337405317, COSV58918296; called by muse, mutect2, varscan2
- ANKH | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99414595; called by muse, mutect2
- ANKH | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763228863, COSV52480958; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs775180361, COSV51843131; called by muse, mutect2, varscan2
- ANKIB1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV99729766; called by muse, mutect2, varscan2
- ANKLE2 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs201575018, COSV100514308; called by muse, mutect2, varscan2
- ANKMY1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs201742759, COSV56029696; called by muse, mutect2, varscan2
- ANKRD12 | c.5816C>A p.A1939D | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100041918; called by muse, mutect2, varscan2
- ANKRD16 | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as COSV99510518; called by muse, mutect2, varscan2
- ANKRD17 | c.7648G>T p.G2550C | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as COSV100429818; called by muse, mutect2, varscan2
- ANKRD17 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV100429820; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1883G>T p.R628I | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62003446; called by muse, mutect2, varscan2
- ANKRD27 | c.2825T>C p.V942A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.097); catalogued as COSV100043089; called by muse, mutect2, varscan2
- ANKRD28 | c.2752C>A p.L918I | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as COSV101080891; called by muse, mutect2, varscan2
- ANKRD29 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs368245092; called by muse, mutect2, varscan2
- ANKRD30A | c.917C>T p.A306V (on ENST00000611781; = p.A250V on NM_052997.2) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100654246; called by muse, mutect2, varscan2
- ANKRD30A | c.3022G>T p.E1008* (on ENST00000611781; = p.E952* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 59/167 reads (35%) | catalogued as rs1564583067, COSV100654250, COSV64604394; called by muse, mutect2, varscan2
- ANKRD30A | c.3122C>T p.A1041V (on ENST00000611781; = p.A985V on NM_052997.2) | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100654252; called by muse, mutect2, varscan2
- ANKRD42 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 150/370 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as rs201777710, COSV99474065; called by muse, mutect2, varscan2
- ANKRD46 | c.471-1G>A p.X157_splice | Splice Site (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100170206; called by muse, mutect2, varscan2
- ANKRD50 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 119/284 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs768232129, COSV101539021; called by muse, mutect2, varscan2
- ANKRD50 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs763266709, COSV72385175; called by muse, mutect2, varscan2
- ANKRD52 | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV99921556; called by muse, mutect2, varscan2
- ANKRD6 | c.1634C>A p.T545N (on ENST00000339746 / NM_001242809.2; = p.T540N on NM_014942.4) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV100330273; called by muse, mutect2, varscan2
- ANKRD7 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 93/276 reads (34%) | catalogued as rs764890081, COSV99501313; called by muse, mutect2, varscan2
- ANKS1B | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 59/164 reads (36%) | catalogued as COSV100247370; called by muse, mutect2, varscan2
- ANO2 | c.1992T>C p.C664= (on ENST00000356134 / NM_001278597.3; = p.C668= on NM_001278596.3) | Splice Region (SNP) | VAF 50/165 reads (30%) | catalogued as rs752157353, COSV100501979; called by muse, mutect2, varscan2
- ANO3 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 76/183 reads (42%) | catalogued as rs775504019, COSV56811269, COSV99879961; called by muse, mutect2, varscan2
- ANO5 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1395517007, COSV100202111; called by muse, mutect2, varscan2
- ANO7 | c.2750G>T p.S917I (on ENST00000274979; = p.S863I on NM_001370694.2) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99239225; called by muse, mutect2, varscan2
- ANP32B | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100233313; called by muse, mutect2, varscan2
- ANP32E | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.899); catalogued as COSV100029749; called by muse, mutect2, varscan2
- ANPEP | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV100263430; called by muse, mutect2, varscan2
- ANTXR1 | c.343G>T p.G115* | Nonsense Mutation (SNP) | VAF 100/308 reads (32%) | catalogued as COSV100362940; called by muse, mutect2, varscan2
- ANTXR1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100362941; called by muse, mutect2, varscan2
- ANXA10 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100829097; called by muse, mutect2, varscan2
- ANXA10 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 122/280 reads (44%) | catalogued as rs1192134579, COSV100829098; called by muse, mutect2, varscan2
- ANXA2R | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.451); catalogued as COSV100148720; called by muse, mutect2, varscan2
- AOC3 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760628746, COSV99520350; called by muse, mutect2
- AOX1 | c.2539G>T p.G847C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101022198; called by muse, mutect2, varscan2
- AOX1 | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV101022199; called by muse, mutect2, varscan2
- AP1B1 | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100434749; called by muse, mutect2, varscan2
- AP1G2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs367610818; called by muse, varscan2
- AP1G2 | c.1622A>G p.D541G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs1366556560, COSV99846315; called by muse, mutect2, varscan2
- AP2M1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1431035134, COSV53047259; called by muse, mutect2
- AP3B2 | c.1138T>G p.F380V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99916881; called by muse, mutect2, varscan2
- APBA1 | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99596924; called by muse, mutect2, varscan2
- APC | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99969600; called by muse, mutect2, varscan2
- APC | c.6971C>A p.P2324H | Missense Mutation (SNP) | VAF 113/257 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969602; called by muse, mutect2, varscan2
- APCDD1L | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100954054; called by muse, mutect2, varscan2
- APEH | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV99609537; called by muse, mutect2, varscan2
- APEH | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV99611016; called by muse, mutect2, varscan2
- APEX2 | c.423-1G>A p.X141_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100895205; called by muse, mutect2, varscan2
- APLP2 | c.1967A>G p.D656G | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99599996; called by muse, mutect2, varscan2
- APMAP | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV99468972; called by muse, mutect2, varscan2
- APOB | c.12508A>G p.N4170D | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99267348; called by muse, mutect2, varscan2
- APOB | c.11157C>A p.F3719L | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV51947110; called by muse, varscan2
- APOB | c.11119G>A p.A3707T | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV99267350; called by muse, varscan2
- APOB | c.5716A>G p.T1906A | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99267356; called by muse, mutect2, varscan2
- APOBEC3A | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99970390; called by muse, mutect2, varscan2
- APOBR | c.2241G>T p.Q747H (on ENST00000431282; = p.Q756H on NM_018690.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); catalogued as COSV99076626; called by muse, mutect2, varscan2
- APOL3 | c.433G>T p.D145Y (on ENST00000349314 / NM_145640.2; = p.D74Y on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100652158; called by muse, mutect2, varscan2
- APOL6 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV101291013; called by muse, mutect2, varscan2
- APP | c.1459-1G>T p.X487_splice | Splice Site (SNP) | VAF 47/127 reads (37%) | catalogued as COSV100696176; called by muse, mutect2, varscan2
- AQP2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52230686; called by muse, mutect2
- AQP4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 117/316 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1195221169, COSV101270555; called by muse, mutect2, varscan2
- AQP9 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 224/570 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs553727841, COSV99583166; called by muse, mutect2, varscan2
- AR | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs773708434, COSV101019131, COSV65957893; called by muse, varscan2
- ARAF | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV99283421; called by muse, mutect2, varscan2
- ARAP2 | c.4444A>G p.M1482V | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100395140; called by muse, mutect2, varscan2
- ARAP2 | c.3895-1G>T p.X1299_splice | Splice Site (SNP) | VAF 187/459 reads (41%) | catalogued as COSV100395141; called by muse, mutect2, varscan2
- AREL1 | c.2327T>G p.I776S | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.055); catalogued as COSV100707641; called by muse, mutect2, varscan2
- AREL1 | c.1771C>A p.L591M | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707642; called by muse, mutect2, varscan2
- ARFGAP3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs756482945, COSV54311590; called by muse, mutect2, varscan2
- ARFGEF1 | c.1787A>G p.Q596R | Missense Mutation (SNP) | VAF 169/402 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as COSV99144103; called by muse, mutect2, varscan2
- ARFGEF2 | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.812); catalogued as COSV100904426; called by muse, mutect2, varscan2
- ARFGEF2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904427; called by muse, mutect2, varscan2
- ARFGEF2 | c.3397C>T p.R1133* | Nonsense Mutation (SNP) | VAF 59/139 reads (42%) | catalogued as COSV64210470; called by muse, mutect2, varscan2
- ARFGEF3 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99294459; called by muse, mutect2, varscan2
- ARFGEF3 | c.4028A>C p.N1343T | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99294460; called by muse, mutect2, varscan2
- ARG1 | c.416A>C p.N139T | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1562359055, COSV99256240; called by muse, mutect2, varscan2
- ARHGAP10 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100331672; called by muse, mutect2, varscan2
- ARHGAP11A | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs375587801; called by muse, mutect2, varscan2
- ARHGAP11A | c.2759G>A p.S920N | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs373408402; called by muse, mutect2, varscan2
- ARHGAP17 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as COSV99253919; called by muse, mutect2, varscan2
- ARHGAP19 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776434645, COSV100363304; called by muse, mutect2, varscan2
- ARHGAP20 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99505046; called by muse, mutect2, varscan2
- ARHGAP24 | c.393C>T p.G131= (on ENST00000395184 / NM_001025616.3; = p.G38= on NM_031305.3) | Splice Region (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99982314; called by muse, mutect2, varscan2
- ARHGAP24 | c.2086A>C p.M696L (on ENST00000395184 / NM_001025616.3; = p.M603L on NM_031305.3) | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99982362; called by muse, mutect2, varscan2
- ARHGAP25 | c.1055T>C p.V352A (on ENST00000409202 / NM_001007231.3; = p.V344A on NM_014882.3) | Missense Mutation (SNP) | VAF 197/537 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.163); catalogued as COSV99771971; called by muse, mutect2, varscan2
- ARHGAP29 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs757995655, COSV53109880; called by muse, mutect2, varscan2
- ARHGAP31 | c.1646C>A p.A549D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99957588; called by muse, mutect2, varscan2
- ARHGAP31 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99957590; called by muse, mutect2, varscan2
- ARHGAP32 | c.5191C>T p.P1731S (on ENST00000310343 / NM_001378025.1; = p.P1382S on NM_014715.4) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100088866; called by muse, mutect2, varscan2
- ARHGAP35 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV101351502; called by muse, mutect2, varscan2
- ARHGAP35 | c.2959G>T p.E987* | Nonsense Mutation (SNP) | VAF 42/116 reads (36%) | catalogued as COSV101351508; called by muse, mutect2, varscan2
- ARHGEF10 | c.2847G>T p.E949D (on ENST00000398564; = p.E924D on NM_014629.4) | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100035375; called by muse, mutect2, varscan2
- ARHGEF11 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs764200211, COSV63812981; called by muse, mutect2, varscan2
- ARHGEF12 | c.4216G>A p.D1406N | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as rs1307381716, COSV100754749; called by muse, mutect2, varscan2
- ARHGEF15 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs750554328, COSV62725606; called by muse, mutect2, varscan2
- ARHGEF15 | c.2313G>T p.K771N | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100730127; called by muse, mutect2
- ARHGEF17 | c.2459G>A p.G820D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs889019633, COSV99736513; called by muse, mutect2, varscan2
- ARHGEF26 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.559); catalogued as rs778948077, COSV100726665, COSV62852700; called by muse, mutect2, varscan2
- ARHGEF26 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100726666; called by muse, mutect2
- ARHGEF26 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774329182, COSV100726400; called by muse, mutect2, varscan2
- ARHGEF28 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99709865; called by muse, mutect2, varscan2
- ARHGEF5 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 84/481 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99283126; called by muse, mutect2, varscan2
- ARHGEF6 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as COSV99166643; called by muse, mutect2, varscan2
- ARHGEF7 | c.712G>A p.V238M (on ENST00000375741 / NM_001113511.2; = p.V60M on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771220906, COSV99522031; called by muse, mutect2
- ARID1A | c.3564G>T p.Q1188H | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100252982; called by muse, mutect2, varscan2
- ARID1A | c.3815C>T p.A1272V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs773264329, COSV61374987; called by muse, mutect2, varscan2
- ARID3B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100654721; called by muse, mutect2
- ARID4B | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 151/424 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99936149; called by muse, mutect2, varscan2
- ARL13B | c.1234C>T p.P412S (on ENST00000394222 / NM_001174150.2; = p.P305S on NM_144996.4) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100114477; called by muse, mutect2, varscan2
- ARL14EP | c.268T>G p.L90V | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); catalogued as COSV56343665; called by muse, mutect2, varscan2
- ARL2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs758628032, COSV55861855; called by muse, mutect2, varscan2
- ARL6IP1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.1); catalogued as COSV100435968; called by muse, mutect2, varscan2
- ARL8A | c.207C>T p.L69= | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as rs767155559, COSV99693378; called by muse, varscan2
- ARL8B | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747994602, COSV56578900; called by muse, mutect2, varscan2
- ARMC1 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99395136; called by muse, mutect2, varscan2
- ARMC12 | c.1012A>T p.N338Y (on ENST00000373866 / NM_001286574.2; = p.N365Y on NM_145028.5) | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs541722832, COSV99849567; called by muse, mutect2, varscan2
- ARMC3 | c.2169C>A p.F723L | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53059310; called by muse, mutect2, varscan2
- ARMC8 | c.389G>A p.R130H (on ENST00000469044 / NM_001363941.2; = p.R116H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs896372361, COSV61768635; called by muse, mutect2, varscan2
- ARMC8 | c.812C>T p.T271I (on ENST00000469044 / NM_001363941.2; = p.T257I on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV100627808; called by muse, mutect2, varscan2
- ARMCX2 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100168253; called by muse, mutect2, varscan2
- ARMCX5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 276/666 reads (41%) | catalogued as COSV99863368; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 212/540 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63439544; called by muse, mutect2, varscan2
- ARMH4 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99958257, COSV99958835; called by muse, mutect2, varscan2
- ARMT1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.275); catalogued as COSV100939838; called by muse, mutect2, varscan2
- ARNTL | c.1147G>T p.G383* (on ENST00000403290 / NM_001297719.2; = p.G382* on NM_001178.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 66/163 reads (40%) | catalogued as COSV100724844; called by muse, mutect2, varscan2
- ARNTL2 | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53828612, COSV99667999; called by muse, mutect2, varscan2
- ARPC3 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 141/355 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99959581; called by muse, mutect2, varscan2
- ARPP21 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs753006497, COSV99493001; called by muse, varscan2
- ARRB1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV100758078; called by muse, mutect2, varscan2
- ARRB1 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100758188; called by muse, mutect2, varscan2
- ARRDC3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1354978153, COSV54364489, COSV99475213; called by muse, mutect2, varscan2
- ARRDC3 | c.613+2T>C p.X205_splice | Splice Site (SNP) | VAF 51/128 reads (40%) | catalogued as COSV99475370; called by muse, mutect2, varscan2
- ARSB | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074023, COSV99365427; called by muse, mutect2, varscan2
- ARSD | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1200074059, COSV54202771, COSV99472318; called by muse, mutect2, varscan2
- ARSG | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV101477920, COSV71593820; called by muse, mutect2, varscan2
- ART1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51702739; called by muse, varscan2
- ASAP2 | c.1827G>T p.Q609H | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs769078162, COSV99856669; called by muse, mutect2, varscan2
- ASB11 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761617786, COSV100729120; called by muse, mutect2, varscan2
- ASB16 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs771202055, COSV53234869; called by muse, mutect2, varscan2
- ASB3 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 109/302 reads (36%) | catalogued as COSV99712398; called by muse, mutect2, varscan2
- ASB3 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 176/437 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1447530587, COSV99712401; called by muse, mutect2, varscan2
- ASB4 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99987213; called by muse, mutect2, varscan2
- ASB7 | c.513C>A p.D171E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.918); catalogued as COSV100235327; called by muse, mutect2, varscan2
- ASCC1 | c.593G>A p.S198N (on ENST00000342444 / NM_001369085.1; = p.S170N on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100403671; called by muse, mutect2, varscan2
- ASCC2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749918340, COSV57075595; called by muse, mutect2, varscan2
- ASCC2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100316445; called by muse, mutect2, varscan2
- ASCC2 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100316447; called by muse, mutect2, varscan2
- ASGR2 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99643143; called by muse, mutect2, varscan2
- ASIC1 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.093); catalogued as COSV99948202; called by muse, varscan2
- ASIC4 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100761907; called by muse, mutect2, varscan2
- ASIC4 | c.1443G>T p.K481N (on ENST00000347842 / NM_182847.3; = p.K500N on NM_018674.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99705235; called by muse, mutect2, varscan2
- ASIC5 | c.1009+1G>A p.X337_splice | Splice Site (SNP) | VAF 61/164 reads (37%) | catalogued as COSV101611164; called by muse, mutect2, varscan2
- ASNS | c.1382A>C p.E461A | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV99446666; called by muse, mutect2, varscan2
- ASPA | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV99559298; called by muse, mutect2, varscan2
- ASPH | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.342); catalogued as COSV100727738; called by muse, mutect2, varscan2
- ASPM | c.9442C>T p.Q3148* | Nonsense Mutation (SNP) | VAF 104/291 reads (36%) | catalogued as COSV99660937; called by muse, mutect2, varscan2
- ASPM | c.3818T>C p.I1273T | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660940; called by muse, mutect2, varscan2
- ASPSCR1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1373378649, COSV100144994; called by muse, varscan2
- ASRGL1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.16); catalogued as rs141369983; called by muse, mutect2, varscan2
- ASS1 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100752789; called by muse, mutect2, varscan2
- ASXL1 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60111699; called by muse, mutect2, varscan2
- ASXL1 | c.2684C>A p.S895Y | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV100040820; called by muse, mutect2, varscan2
- ATAD2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54881389, COSV54888536; called by muse, mutect2, varscan2
- ATAD3B | c.427G>A p.A143T (on ENST00000308647; = p.A249T on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1316562285, COSV100426584; called by muse, mutect2, varscan2
- ATF2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV99908937; called by muse, mutect2, varscan2
- ATF6 | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV100909409; called by muse, mutect2, varscan2
- ATF7IP | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 78/221 reads (35%) | catalogued as COSV99662029; called by muse, mutect2, varscan2
- ATF7IP | c.2792G>T p.R931I | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV99662031; called by muse, mutect2, varscan2
- ATF7IP2 | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 54/141 reads (38%) | catalogued as COSV100202738; called by muse, mutect2
- ATG16L1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1420330153, COSV61465360; called by muse, mutect2
- ATG16L2 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs1565267692, COSV58362561; called by muse, mutect2
- ATG4C | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 136/325 reads (42%) | catalogued as COSV100508505; called by muse, mutect2, varscan2
- ATG9A | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs762480185, COSV54698814, COSV54699324; called by muse, mutect2, varscan2
- ATG9A | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100037147; called by muse, mutect2
- ATM | c.8155C>T p.R2719C | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs138526014, CM157955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100214749; called by muse, mutect2, varscan2
- ATN1 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs1156733389, COSV100755935, COSV63112582; called by muse, mutect2, varscan2
- ATOH8 | c.602A>C p.N201T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.624); catalogued as rs768036689, COSV100092811; called by muse, mutect2, varscan2
- ATP10A | c.3213G>T p.E1071D | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100791455; called by muse, mutect2, varscan2
- ATP10A | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763990614, COSV63515700; called by muse, mutect2, varscan2
- ATP10A | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.873); catalogued as COSV100791458; called by muse, mutect2, varscan2
- ATP10B | c.4256C>T p.A1419V | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100515606; called by muse, mutect2, varscan2
- ATP10B | c.3396C>A p.F1132L | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59153682; called by muse, mutect2, varscan2
- ATP10D | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as COSV99906070; called by muse, mutect2, varscan2
- ATP10D | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 238/581 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs550923470, COSV56704903; called by muse, mutect2, varscan2
- ATP11B | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as COSV100017942; called by muse, mutect2, varscan2
- ATP11C | c.3144G>A p.W1048* | Nonsense Mutation (SNP) | VAF 83/205 reads (40%) | catalogued as COSV100558427; called by muse, mutect2, varscan2
- ATP11C | c.3105C>A p.F1035L | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100558430; called by muse, mutect2, varscan2
- ATP12A | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV99518271; called by muse, mutect2, varscan2
- ATP13A1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs763788257, COSV99366519; called by muse, varscan2
- ATP13A3 | c.2893G>A p.D965N | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV99757518; called by muse, mutect2, varscan2
- ATP13A3 | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757519; called by muse, mutect2, varscan2
- ATP13A3 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 172/415 reads (41%) | catalogued as COSV99757525; called by muse, mutect2, varscan2
- ATP13A4 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795134; called by muse, mutect2, varscan2
- ATP13A5 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs887711341, COSV100665591; called by muse, mutect2, varscan2
- ATP1A1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1429384765, COSV55189682, COSV55192203; called by muse, mutect2, varscan2
- ATP1A1 | c.2368T>G p.F790V | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99814709; called by muse, mutect2, varscan2
- ATP1A1 | c.3042C>T p.G1014= | Splice Region (SNP) | VAF 82/220 reads (37%) | catalogued as COSV55190117; called by muse, mutect2, varscan2
- ATP1A2 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs540087535, COSV100768100; called by muse, mutect2, varscan2
- ATP1B3 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV99657521; called by muse, mutect2, varscan2
- ATP1B3 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99657524; called by muse, mutect2, varscan2
- ATP2A1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772693650, COSV100837078, COSV63920075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B1 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99666048; called by muse, mutect2, varscan2
- ATP2B3 | c.3043G>A p.G1015R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV99685533; called by muse, mutect2, varscan2
- ATP2C2 | c.2051C>A p.S684Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as COSV99298518; called by muse, varscan2
- ATP2C2 | c.2103G>T p.E701D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99298522; called by muse, varscan2
- ATP4A | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778187193, COSV99382967; called by muse, mutect2, varscan2
- ATP4A | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99382968; called by muse, mutect2, varscan2
- ATP5F1B | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV100008206; called by muse, mutect2, varscan2
- ATP5MC3 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.403); catalogued as COSV99507222; called by muse, mutect2, varscan2
- ATP5PB | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773316141, COSV100867651; called by muse, mutect2, varscan2
- ATP6V0A1 | c.389T>G p.F130C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs901191354, COSV99231466; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100023542; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1927T>A p.F643I | Missense Mutation (SNP) | VAF 163/382 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100023545; called by muse, mutect2, varscan2
- ATP6V0A4 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775496062, COSV59479383; called by muse, varscan2
- ATP6V1B1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52266405, COSV99313558; called by muse, mutect2, varscan2
- ATP6V1B1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576236297, COSV99314415; called by muse, mutect2, varscan2
- ATP6V1B2 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99369575; called by muse, mutect2, varscan2
- ATP7A | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 115/311 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100431469; called by muse, mutect2, varscan2
- ATP7A | c.4455C>A p.H1485Q | Missense Mutation (SNP) | VAF 250/659 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100431473; called by muse, mutect2, varscan2
- ATP7B | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99666869; called by muse, mutect2, varscan2
- ATP8A1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100047123; called by muse, mutect2, varscan2
- ATP8A2 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs367802091; called by muse, mutect2, varscan2
- ATP8B1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762857853, COSV52173943; called by muse, mutect2, varscan2
- ATP8B1 | c.247A>C p.K83Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99377712; called by muse, mutect2, varscan2
- ATP9A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV100125492; called by muse, mutect2, varscan2
- ATP9A | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as rs149707066; called by muse, mutect2, varscan2
- ATP9B | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100304042; called by muse, mutect2, varscan2
- ATPAF2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV58264716; called by muse, mutect2
- ATR | c.2878C>T p.R960* | Nonsense Mutation (SNP) | VAF 20/268 reads (7%) | catalogued as COSV100638505; called by muse, mutect2
- ATR | c.611T>G p.F204C | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100638507; called by muse, mutect2, varscan2
- ATRN | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99497725; called by muse, mutect2, varscan2
- ATRNL1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 243/651 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV100746746; called by muse, mutect2, varscan2
- ATRNL1 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV61821130; called by muse, mutect2, varscan2
- ATRX | c.3815C>A p.A1272D | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100971284; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 311/746 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- ATRX | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 167/445 reads (38%) | catalogued as COSV64873757, COSV64875914; called by muse, mutect2, varscan2
- ATXN2L | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100294980; called by muse, mutect2, varscan2
- ATXN2L | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs769628304, COSV57371698; called by muse, mutect2, varscan2
- ATXN3L | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 187/431 reads (43%) | catalogued as COSV101019547; called by muse, mutect2, varscan2
- ATXN7L2 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs767529526, COSV100149923; called by muse, mutect2, varscan2
- AUTS2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 3/6 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs1277387034, COSV61424313; called by mutect2, varscan2
- AVPR1A | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs866629670, COSV54546637, COSV54547971; called by muse, mutect2, varscan2
- AWAT2 | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99339751; called by muse, mutect2, varscan2
- AXL | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99997050; called by muse, mutect2, varscan2
- B3GALNT1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100252138; called by muse, mutect2, varscan2
- B3GALT4 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV65851654; called by muse, mutect2, varscan2
- B3GLCT | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV58454356; called by muse, mutect2, varscan2
- B3GNT2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 152/395 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1221913105, COSV100114272; called by muse, mutect2, varscan2
- B3GNT5 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV58476873; called by muse, mutect2, varscan2
- B4GALNT2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100302717; called by muse, mutect2, varscan2
- B4GALNT3 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56756198, COSV99843466; called by muse, mutect2, varscan2
- B4GAT1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60819620; called by muse, mutect2, varscan2
- BACE1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs552807233, COSV100326901; called by muse, mutect2, varscan2
- BACE1 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as COSV100326902; called by muse, mutect2, varscan2
- BACE1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 146/380 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100475274; called by muse, mutect2, varscan2
- BACE2 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753171242, COSV57738271; called by muse, mutect2, varscan2
- BACH2 | c.2498A>G p.D833G | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100000616; called by muse, mutect2, varscan2
- BACH2 | c.1538T>C p.L513S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as COSV100000619; called by muse, mutect2, varscan2
- BACH2 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100000622; called by muse, mutect2, varscan2
- BAG3 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100958285; called by muse, mutect2, varscan2
- BAG4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99782003; called by muse, mutect2, varscan2
- BAIAP2L1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 174/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773272850, COSV50056847; called by muse, mutect2, varscan2
- BAIAP3 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV99136351; called by muse, mutect2
- BAIAP3 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs150054474; called by muse, varscan2
- BANK1 | c.1901-1G>T p.X634_splice | Splice Site (SNP) | VAF 134/382 reads (35%) | catalogued as COSV100536724; called by muse, mutect2, varscan2
- BARD1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs587782248, COSV99639623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 63/162 reads (39%) | catalogued as COSV100701203, COSV62411268; called by muse, mutect2, varscan2
- BAZ1A | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.644); catalogued as COSV100701204; called by muse, mutect2, varscan2
- BAZ2A | c.4822C>T p.P1608S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99467389; called by muse, mutect2, varscan2
- BAZ2A | c.2198A>G p.Q733R | Missense Mutation (SNP) | VAF 209/521 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV99467396; called by muse, mutect2, varscan2
- BAZ2A | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762450030, COSV99467404; called by muse, mutect2, varscan2
- BAZ2B | c.1811C>A p.S604Y | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58596642; called by muse, mutect2, varscan2
- BBOF1 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV101223935; called by muse, mutect2, varscan2
- BBS10 | c.2114T>C p.I705T | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs980951815, COSV101283421; called by muse, mutect2, varscan2
- BBS2 | c.637T>C p.Y213H | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs763075980, COSV99802730; called by muse, mutect2, varscan2
- BBS7 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765782762, COSV99145046; called by muse, mutect2, varscan2
- BBS7 | c.1154T>G p.F385C | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV52655411; called by muse, mutect2, varscan2
- BCAS3 | c.2755C>T p.P919S (on ENST00000390652 / NM_001353144.2; = p.P904S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.979); catalogued as COSV66770428; called by muse, mutect2, varscan2
- BCAS4 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99372749; called by muse, mutect2, varscan2
- BCAT1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678889; called by muse, varscan2
- BCAT1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs756333156, COSV99678892; called by muse, mutect2, varscan2
- BCAT2 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100302534; called by muse, mutect2, varscan2
- BCAT2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs372825449, COSV60271778; called by muse, varscan2
- BCCIP | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.09); catalogued as rs1401782684, COSV52939292; called by muse, mutect2, varscan2
- BCCIP | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as COSV99501887; called by muse, mutect2, varscan2
- BCKDHB | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 281/697 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as rs748693585, COSV57519100; called by muse, mutect2, varscan2
- BCL11A | c.1948T>A p.F650I (on ENST00000335712 / NM_001365609.1; = p.F684I on NM_018014.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100186316; called by muse, mutect2, varscan2
- BCL2L14 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99845238; called by muse, mutect2, varscan2
- BCL3 | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV99378291; called by muse, mutect2, varscan2
- BCL7C | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs758429606, COSV53063060; called by muse, mutect2
- BCL9L | c.1856G>A p.S619N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773230307, COSV99419962; called by muse, varscan2
- BCLAF1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs62431287, COSV50356735; ClinVar: benign; called by muse, mutect2, varscan2
- BCLAF3 | c.1103A>C p.K368T | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100503380; called by muse, mutect2, varscan2
- BCO2 | c.736+1G>A p.X246_splice | Splice Site (SNP) | VAF 113/275 reads (41%) | catalogued as COSV100730448; called by muse, mutect2, varscan2
- BCO2 | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 50/130 reads (38%) | catalogued as COSV100730450; called by muse, mutect2, varscan2
- BCOR | c.2863C>A p.L955M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as rs766898838, COSV100652789; called by muse, mutect2, varscan2
- BCOR | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as rs148886271, COSV60716507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCORL1 | c.4306-1G>T p.X1436_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | catalogued as COSV99500570; called by muse, mutect2, varscan2
- BCORL1 | c.4696+1G>A p.X1566_splice | Splice Site (SNP) | VAF 67/184 reads (36%) | catalogued as COSV99500573; called by muse, mutect2, varscan2
- BDKRB2 | c.1028C>A p.S343Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100021394; called by muse, mutect2, varscan2
- BEND3 | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100944662; called by muse, mutect2, varscan2
- BET1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775800524, COSV99747369; called by muse, mutect2, varscan2
- BEX1 | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 197/581 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV101022506; called by muse, mutect2, varscan2
- BEX5 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 233/527 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.166); catalogued as COSV100375080; called by muse, mutect2, varscan2
- BHMT | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.848); catalogued as rs762015001, COSV57154220; called by muse, mutect2, varscan2
- BICD1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99862858; called by muse, mutect2, varscan2
- BICDL1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99985930; called by muse, mutect2
- BICRAL | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100018363; called by muse, mutect2, varscan2
- BIRC2 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99926865; called by muse, mutect2, varscan2
- BIRC2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 178/452 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV57163290; called by muse, mutect2, varscan2
- BIRC6 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as rs1022274342, COSV101429309, COSV70205028; called by muse, mutect2, varscan2
- BIRC6 | c.6484G>A p.V2162I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.071); catalogued as COSV101428642; called by muse, mutect2, varscan2
- BIRC6 | c.6871C>T p.R2291C | Missense Mutation (SNP) | VAF 116/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771264582, COSV70196203, COSV70202819; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV99959032; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4337G>A p.R1446Q | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs377390651, COSV63246081; called by muse, mutect2, varscan2
- BLNK | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV99814157; called by muse, mutect2, varscan2
- BLVRA | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as COSV99646089; called by muse, mutect2, varscan2
- BMI1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs753450025, COSV100936465; called by muse, mutect2, varscan2
- BMP2 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV66578229; called by muse, mutect2, varscan2
- BMP5 | c.1217T>A p.V406D | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896254; called by muse, mutect2, varscan2
- BMP5 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 79/181 reads (44%) | catalogued as rs751770025, COSV63702268; called by muse, mutect2, varscan2
- BMPER | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1562770532, COSV99780320; called by muse, mutect2, varscan2
- BMPR1A | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV100923695; called by muse, mutect2, varscan2
- BMPR1B | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as CM121721, COSV99216198; called by muse, mutect2, varscan2
- BMPR2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs748889215, COSV101001613, COSV65812397; called by muse, mutect2, varscan2
- BMPR2 | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1470605273, COSV101001614; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 69/190 reads (36%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BOC | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV56355922; called by muse, mutect2, varscan2
- BOC | c.2373G>T p.Q791H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849222; called by muse, mutect2, varscan2
- BOD1L1 | c.9070C>T p.R3024C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369852170; called by muse, mutect2, varscan2
- BOD1L1 | c.8909G>A p.R2970H | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs140335847; called by muse, mutect2, varscan2
- BOD1L1 | c.7282G>A p.A2428T | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs905526771, COSV99240131; called by muse, mutect2, varscan2
- BOD1L1 | c.6611C>A p.P2204H | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV99240134; called by muse, mutect2, varscan2
- BPHL | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100984519; called by muse, mutect2, varscan2
- BPHL | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs749536830, COSV66743849; called by muse, mutect2, varscan2
- BPIFA1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs550742438, COSV62824572; called by muse, varscan2
- BPIFB2 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99401613; called by muse, mutect2, varscan2
- BPIFC | c.927T>G p.I309M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100301220; called by muse, mutect2, varscan2
- BRAF | c.1645C>T p.R549* (on ENST00000288602 / NM_001374244.1; = p.R509* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | catalogued as rs1485437761, COSV56181083; called by muse, mutect2, varscan2
- BRAP | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370834616; called by muse, mutect2, varscan2
- BRCA2 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100564000; called by muse, mutect2, varscan2
- BRCA2 | c.2600C>T p.T867I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.508); catalogued as COSV101204589; called by muse, mutect2, varscan2
- BRCC3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as COSV100341750; called by muse, mutect2, varscan2
- BRD2 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.306); catalogued as COSV100875804; called by muse, mutect2, varscan2
- BRD7 | c.998T>A p.L333H | Missense Mutation (SNP) | VAF 348/937 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.792); catalogued as COSV101165037; called by muse, mutect2, varscan2
- BRD8 | c.3205T>C p.C1069R | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); catalogued as COSV99648946; called by muse, mutect2, varscan2
- BRDT | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs376776587; called by muse, mutect2, varscan2
- BRF1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV100526892; called by muse, mutect2, varscan2
- BRINP1 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); catalogued as COSV99776613; called by muse, mutect2, varscan2
- BRINP2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1419220723, COSV64175373; called by muse, mutect2, varscan2
- BRINP2 | c.2087C>A p.A696D | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100838297; called by muse, mutect2, varscan2
- BRIP1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.315); catalogued as COSV99370800; called by muse, mutect2, varscan2
- BRMS1L | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99396797; called by muse, mutect2, varscan2
- BROX | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100388405; called by muse, mutect2, varscan2
- BROX | c.1217C>A p.T406N | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100572314; called by muse, mutect2, varscan2
- BRPF3 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as rs1031408587, COSV100326100; called by muse, mutect2, varscan2
- BRPF3 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.947); catalogued as COSV100326103; called by muse, mutect2, varscan2
- BRPF3 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100326105; called by muse, mutect2, varscan2
- BRS3 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65710838, COSV65710893; called by muse, mutect2, varscan2
- BRSK1 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100510833; called by muse, mutect2, varscan2
- BRSK1 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV100474491; called by muse, mutect2, varscan2
- BRSK2 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100373043; called by muse, mutect2
- BRWD1 | c.4022C>A p.P1341H | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313914; called by muse, mutect2, varscan2
- BSCL2 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99628445; called by muse, mutect2, varscan2
- BSN | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99609536; called by muse, mutect2
- BSND | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV100987609, COSV100987652; called by muse, mutect2, varscan2
- BSPRY | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs376745013; called by muse, mutect2, varscan2
- BTAF1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs376933322, COSV56439593; called by muse, mutect2, varscan2
- BTAF1 | c.2748T>A p.N916K | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99795697; called by muse, mutect2, varscan2
- BTBD1 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 300/772 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375946711, COSV55602936; called by muse, varscan2
- BTBD11 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs369384423, COSV55023111; called by muse, mutect2, varscan2
- BTBD11 | c.2890G>T p.E964* (on ENST00000280758 / NM_001018072.2; = p.E501* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 100/263 reads (38%) | catalogued as COSV99776732; called by muse, mutect2, varscan2
- BTBD16 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs769336919, COSV99584985; called by muse, mutect2, varscan2
- BTBD3 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 167/423 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99656063; called by muse, mutect2, varscan2
- BTK | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as rs1555977832, COSV100437840; called by muse, mutect2, varscan2
- BTN1A1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV55067744; called by muse, mutect2, varscan2
- BTN2A2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs769740966, COSV61858340; called by muse, mutect2, varscan2
- BTN3A1 | c.1041A>C p.K347N | Missense Mutation (SNP) | VAF 115/339 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV99176052; called by muse, mutect2, varscan2
- BTN3A3 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1424115727, COSV99765014; called by muse, mutect2, varscan2
- BTNL8 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.192); catalogued as rs1278140311, COSV99180557; called by muse, mutect2
- BTNL8 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs375021363; called by muse, mutect2
- BUB1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 276/734 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100241534, COSV57067869; called by muse, mutect2, varscan2
- BZW2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51754566, COSV99334819; called by muse, mutect2, varscan2
- C10orf71 | c.1949G>A p.C650Y | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV100110556; called by muse, mutect2, varscan2
- C10orf90 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 129/318 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99504873; called by muse, mutect2, varscan2
- C12orf56 | c.1147C>A p.L383I (on ENST00000543942 / NM_001170633.2; = p.L223I on NM_001099676.3) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100399759; called by muse, mutect2, varscan2
- C16orf89 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100280933; called by muse, mutect2, varscan2
- C17orf97 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789377, COSV64076217; called by muse, mutect2, varscan2
- C18orf21 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 87/239 reads (36%) | catalogued as COSV99321664; called by muse, mutect2, varscan2
- C18orf54 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100266671; called by muse, mutect2, varscan2
- C19orf44 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1282625596, COSV99685399; called by muse, mutect2, varscan2
- C19orf57 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs144556741; called by muse, varscan2
- C1GALT1C1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.355); catalogued as rs770339110, COSV100485641; called by muse, mutect2, varscan2
- C1QTNF1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs370218119; called by muse, mutect2, varscan2
- C1QTNF7 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 187/430 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99765428; called by muse, mutect2, varscan2
- C1QTNF9 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV100130003; called by muse, mutect2, varscan2
- C1QTNF9B | c.230-1G>T p.X77_splice | Splice Site (SNP) | VAF 25/132 reads (19%) | catalogued as COSV101158619; called by muse, mutect2, varscan2
- C1orf100 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100353457; called by muse, mutect2, varscan2
- C1orf174 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as rs751234275, COSV100851824; called by muse, mutect2, varscan2
8,379 further variants in this file (6,089 protein-altering or splice-affecting, 2,082 silent, 208 other) are not listed here.
